Somatic mutation profile of tumor specimen TCGA-DD-AAE6-01A (aliquot TCGA-DD-AAE6-01A-11D-A40R-10) from TCGA case TCGA-DD-AAE6, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 59.6 years (21,764 days).
Specimen TCGA-DD-AAE6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d376ca8-3e22-47ec-a5b0-855fc0d765e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAE6-10A (Blood Derived Normal), aliquot TCGA-DD-AAE6-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46c47170-f60f-4519-81b8-a8246ffc0635

The open-access MAF lists 102 somatic variants for this specimen: 66 protein-altering or splice-affecting, 35 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 35, Nonsense Mutation 8, Splice Site 3, Frame Shift Ins 2, RNA 1, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA2 | c.4595G>A p.R1532H (on ENST00000614293; = p.R1502H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.092); catalogued as rs755244581, COSV99688408; called by muse, mutect2, varscan2
- ANKMY2 | c.947A>T p.D316V | Missense Mutation (SNP) | VAF 71/179 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as COSV100187188, COSV100187331; called by muse, mutect2, varscan2
- APOBR | c.809C>A p.A270E | Missense Mutation (SNP) | VAF 68/169 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.234); catalogued as COSV100112928; called by muse, mutect2, varscan2
- ARHGAP35 | c.3080G>A p.S1027N | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as rs1221753325, COSV101351673; called by muse, mutect2, varscan2
- ARID1B | c.1843C>T p.Q615* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as rs1554265306, COSV51687240; called by muse, mutect2, varscan2
- ATRNL1 | c.2929T>A p.S977T | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.296); catalogued as COSV100372719; called by muse, mutect2, varscan2
- AXIN1 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 33/34 reads (97%) | catalogued as COSV51990202; called by muse, mutect2, varscan2
- BRD7 | c.1642G>T p.E548* | Nonsense Mutation (SNP) | VAF 24/24 reads (100%) | catalogued as COSV99576360; called by muse, mutect2, varscan2
- BTRC | c.267C>G p.N89K (on ENST00000370187 / NM_033637.4; = p.N53K on NM_003939.5) | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV100926618; called by muse, mutect2, varscan2
- C2CD3 | c.4975G>A p.V1659I | Missense Mutation (SNP) | VAF 48/52 reads (92%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV100487388, COSV58089372; called by muse, mutect2, varscan2
- CACNA1I | c.274A>G p.N92D | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100361492; called by muse, mutect2, varscan2
- CCDC60 | c.281G>A p.R94K | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV59544341; called by muse, mutect2, varscan2
- CCDC80 | c.2728G>C p.G910R | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99245272; called by muse, mutect2, varscan2
- CD80 | c.392T>C p.L131P | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99958415; called by muse, mutect2, varscan2
- CSF2RB | c.641C>T p.T214I | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV99454420; called by muse, mutect2, varscan2
- DIO3 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.87); catalogued as COSV100832271; called by muse, mutect2, varscan2
- EPB41L5 | c.700A>G p.M234V | Missense Mutation (SNP) | VAF 248/382 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99759224; called by muse, mutect2, varscan2
- EPHA4 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756184907, COSV56025592, COSV56038461; called by muse, mutect2, varscan2
- EXOSC10 | c.2533C>A p.Q845K (on ENST00000376936 / NM_001001998.3; = p.Q820K on NM_002685.4) | Missense Mutation (SNP) | VAF 75/137 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.195); catalogued as COSV100442885; called by muse, mutect2, varscan2
- GPR161 | c.1274C>A p.P425H | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.015); catalogued as rs371331680, COSV54791473; called by muse, mutect2, varscan2
- HCRTR1 | c.116A>G p.Y39C | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101036308; called by muse, mutect2, varscan2
- HMCN1 | c.7119del p.D2373Efs*6 | Frame Shift Del (DEL) | VAF 79/231 reads (34%) | catalogued as COSV54931942; called by mutect2, pindel, varscan2
- HMGCR | c.900A>T p.R300S | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.115); catalogued as COSV99843481; called by muse, mutect2, varscan2
- JAKMIP3 | c.1723C>T p.R575W | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs768264283, COSV53822470; called by muse, mutect2, varscan2
- KAT6A | c.2785C>T p.Q929* | Nonsense Mutation (SNP) | VAF 32/79 reads (41%) | catalogued as COSV99705859; called by muse, mutect2, varscan2
- KIF17 | c.1343G>A p.R448K | Missense Mutation (SNP) | VAF 72/125 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99929719; called by muse, mutect2, varscan2
- KIF22 | c.1832G>T p.G611V | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99361483; called by muse, mutect2, varscan2
- KRT84 | c.313C>G p.L105V | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.036); catalogued as COSV99231041; called by muse, mutect2, varscan2
- LCE2B | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV100909281; called by muse, mutect2
- MARVELD2 | c.709G>C p.G237R | Missense Mutation (SNP) | VAF 60/117 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100347928; called by muse, mutect2, varscan2
- MPP6 | c.1310A>G p.N437S | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.401); catalogued as rs74407305, COSV99757838; called by muse, mutect2, varscan2
- MRPS35 | c.329A>G p.N110S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs370001683, COSV99317641; called by muse, mutect2, varscan2
- NXF1 | c.1300G>T p.E434* | Nonsense Mutation (SNP) | VAF 58/118 reads (49%) | catalogued as COSV99586438; called by muse, mutect2, varscan2
- OR10J3 | c.740C>T p.T247I | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.311); catalogued as COSV59955299, COSV59955502; called by muse, mutect2, varscan2
- OR4C12 | c.722A>G p.H241R | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100078676; called by muse, mutect2, varscan2
- OR52A5 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs1199724012, COSV100263567; called by muse, mutect2, varscan2
- OR8K3 | c.773A>T p.Y258F | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV100449893; called by muse, mutect2, varscan2
- PAPOLB | c.92T>C p.V31A | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV101271617; called by muse, mutect2, varscan2
- PAPPA | c.4103A>G p.K1368R | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100073982, COSV100075233; called by muse, mutect2, varscan2
- PCDHGA11 | c.1625C>T p.P542L | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); catalogued as COSV99546441; called by muse, mutect2, varscan2
- PLIN1 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as rs766470624, COSV100261703; called by muse, mutect2, varscan2
- PPP1R16A | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs746197210, COSV52953042; called by muse, mutect2, varscan2
- PPP1R7 | c.156G>C p.E52D | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV99298190; called by muse, mutect2, varscan2
- PSMA5 | c.191T>C p.I64T | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV99600674; called by muse, mutect2, varscan2
- PTPN14 | c.510+1G>A p.X170_splice | Splice Site (SNP) | VAF 99/776 reads (13%) | catalogued as COSV100872414; called by muse, mutect2, varscan2
- RAB2B | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.029); catalogued as COSV99398563, COSV99398586; called by muse, mutect2
- RHOC | c.350A>G p.N117S | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.74); PolyPhen benign (0.067); catalogued as COSV99588499; called by muse, mutect2, varscan2
- RPS6KA5 | c.2260G>T p.E754* | Nonsense Mutation (SNP) | VAF 54/60 reads (90%) | catalogued as COSV100003209, COSV56224019; called by muse, mutect2, varscan2
- SCGB1D2 | c.247A>C p.K83Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.589); catalogued as COSV99793600; called by muse, mutect2, varscan2
- SEMA3E | c.337-1G>T p.X113_splice | Splice Site (SNP) | VAF 34/80 reads (43%) | catalogued as rs1311561381, COSV57081072; called by muse, mutect2, varscan2
- SH3TC2 | c.1290G>T p.E430D | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as COSV100102126, COSV100102316; called by muse, mutect2, varscan2
- SLC11A1 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 10/93 reads (11%) | catalogued as COSV99262445; called by muse, mutect2, varscan2
- SPTA1 | c.3477+2T>A p.X1159_splice | Splice Site (SNP) | VAF 31/184 reads (17%) | catalogued as COSV100935536; called by muse, mutect2, varscan2
- SPTY2D1 | c.1688T>A p.L563Q | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.701); catalogued as COSV100311847; called by muse, mutect2, varscan2
- SSX2IP | c.1657A>T p.I553L | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100642719; called by muse, mutect2, varscan2
- SYNJ2 | c.1812G>T p.K604N | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as COSV100840642; called by muse, mutect2, varscan2
- TDRD5 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99677108; called by muse, mutect2
- TEX55 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 157/444 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1363537142, COSV55213249; called by muse, varscan2
- TMEM132B | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 84/249 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.235); catalogued as rs372738030, COSV100170826; called by muse, mutect2, varscan2
- TNR | c.1842G>A p.W614* | Nonsense Mutation (SNP) | VAF 20/132 reads (15%) | catalogued as COSV99691450; called by muse, mutect2, varscan2
- TP53 | c.423_427dup p.V143Afs*29 | Frame Shift Ins (INS) | VAF 28/38 reads (74%) | catalogued as COSV52805154, COSV99470544; called by mutect2, varscan2
- TRPC5 | c.277A>T p.S93C | Missense Mutation (SNP) | VAF 83/180 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV99462641; called by muse, mutect2, varscan2
- TSPAN19 | c.664C>A p.L222I | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.301); catalogued as rs1463170597, COSV101468118; called by muse, mutect2, varscan2
- UNC45B | c.2659G>A p.V887M | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT tolerated (0.94); PolyPhen benign (0.038); catalogued as rs868654026, COSV99269219; called by muse, mutect2, varscan2
- ZNF17 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100300171; called by muse, mutect2, varscan2
- PSEN2 | c.606dup p.T203Hfs*61 | Frame Shift Ins (INS) | VAF 23/116 reads (20%) | called by mutect2, pindel, varscan2
- ANKFN1 | c.1674A>T p.S558= | Silent (SNP) | VAF 75/153 reads (49%) | catalogued as COSV100594169; called by muse, mutect2, varscan2
- ANKLE1 | c.588G>A p.G196= (on ENST00000394458; = p.G142= on NM_152363.6) | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as rs368355885; called by muse, mutect2, varscan2
- CCDC74B | c.954C>T p.D318= | Silent (SNP) | VAF 30/127 reads (24%) | catalogued as COSV100134729; called by muse, mutect2, varscan2
- CDCP2 | c.18G>C p.G6= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV100313674; called by muse, mutect2, varscan2
- CLP1 | c.417G>A p.V139= | Silent (SNP) | VAF 40/93 reads (43%) | catalogued as COSV100239940; called by muse, mutect2, varscan2
- CYP2J2 | c.573C>T p.I191= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as rs1457562025, COSV100968125; called by muse, mutect2, varscan2
- DDX46 | c.1455C>T p.I485= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as rs1257341148, COSV100844926; called by muse, mutect2, varscan2
- DHRS3 | c.171G>A p.E57= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as COSV100879678, COSV66108919; called by muse, mutect2, varscan2
- DMRTA2 | c.213G>A p.A71= | Silent (SNP) | VAF 43/90 reads (48%) | catalogued as COSV101288906; called by muse, mutect2, varscan2
- DYM | c.441T>G p.L147= | Silent (SNP) | VAF 8/203 reads (4%) | catalogued as COSV99494144, COSV99494165; called by muse, mutect2
- EPHA4 | c.72G>A p.R24= | Silent (SNP) | VAF 41/107 reads (38%) | catalogued as rs761616774, COSV99917446; called by muse, mutect2, varscan2
- FBF1 | c.2736C>T p.D912= (on ENST00000586717; = p.D926= on NM_001319193.1) | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV100045583; called by muse, mutect2, varscan2
- GNAS | c.1101C>T p.A367= | Silent (SNP) | VAF 47/147 reads (32%) | catalogued as COSV100007598; called by muse, mutect2, varscan2
- IREB2 | c.1668C>T p.Y556= | Silent (SNP) | VAF 21/118 reads (18%) | catalogued as rs747554380, COSV51921648; called by muse, mutect2, varscan2
- KCNT1 | c.1389C>T p.A463= (on ENST00000488444; = p.A482= on NM_020822.3) | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV53712612, COSV99706631; called by muse, mutect2, varscan2
- LOXL3 | c.669G>A p.K223= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs1250970750, COSV99284199; called by muse, mutect2, varscan2
- MMRN1 | c.1647A>G p.L549= | Silent (SNP) | VAF 69/70 reads (99%) | catalogued as COSV53336799; called by muse, mutect2, varscan2
- OR2G3 | c.279T>G p.T93= | Silent (SNP) | VAF 47/170 reads (28%) | catalogued as COSV60680716, COSV60681025; called by muse, mutect2, varscan2
- OR2T10 | c.312C>T p.Y104= | Silent (SNP) | VAF 25/200 reads (13%) | catalogued as rs1360324084, COSV100393812; called by muse, mutect2, varscan2
- PRRC2A | c.5865T>C p.D1955= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV99277600; called by muse, mutect2, varscan2
- PSMB5 | c.591C>T p.V197= | Silent (SNP) | VAF 23/193 reads (12%) | catalogued as COSV100557418; called by muse, mutect2, varscan2
- RASGRP3 | c.1197G>A p.V399= (on ENST00000402538 / NM_001349975.2; = p.V398= on NM_015376.2 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 124/262 reads (47%) | catalogued as rs1250835895, COSV101274901; called by muse, varscan2
- SHANK2 | c.2685C>T p.P895= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV99575968; called by muse, mutect2, varscan2
- SLC12A5 | c.1452C>T p.V484= (on ENST00000454036 / NM_001134771.2; = p.V461= on NM_020708.5) | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as COSV54799939, COSV99716789; called by muse, mutect2
- SLC12A9 | c.522G>A p.L174= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs767146725, COSV99308173; called by muse, mutect2, varscan2
- SLC6A19 | c.1197C>G p.A399= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as COSV100443768; called by muse, mutect2, varscan2
- TBC1D19 | c.1029A>G p.S343= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV99336789; called by muse, mutect2, varscan2
- TMPO | c.393T>G p.P131= | Silent (SNP) | VAF 39/98 reads (40%) | catalogued as COSV99702173; called by muse, mutect2, varscan2
- TMPRSS3 | c.822A>C p.L274= | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as COSV99368674; called by muse, mutect2, varscan2
- TPTE | c.1005G>A p.A335= (on ENST00000618007 / NM_199261.4; = p.A317= on NM_199259.4) | Silent (SNP) | VAF 114/741 reads (15%) | catalogued as rs755583335; called by muse, mutect2, varscan2
- TSPEAR | c.696C>T p.S232= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs1555915515, COSV100555407; called by muse, mutect2, varscan2
- VWA1 | c.360C>T p.A120= | Silent (SNP) | VAF 51/87 reads (59%) | catalogued as COSV100100804; called by muse, mutect2, varscan2
- ZBTB5 | c.1011T>C p.P337= | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as COSV100312944; called by muse, mutect2, varscan2
- ZDHHC2 | c.192A>G p.A64= | Silent (SNP) | VAF 89/96 reads (93%) | catalogued as COSV100025159; called by muse, mutect2, varscan2
- ZEB2 | c.2115C>T p.S705= | Silent (SNP) | VAF 38/114 reads (33%) | catalogued as rs1356643964, COSV100356850; called by muse, mutect2, varscan2
- TP73-AS1 | n.1185C>G | RNA (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2
